MMRF case MMRF_2128 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cc6c27ff-2e4b-4fe0-97cc-e90a9fe2151c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.3 years (24,231 days); ISS stage: I; Days to last known disease status: 898 days (2.5 years); Days to last follow up: 898 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 323 days; Days to treatment end: 343 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 1): M Protein 2.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 45.7 mg/dL; Immunoglobulin G 30.3 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.14 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 9.5 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 0.039 mg/dL.
- Day 115 (ECOG 1): M Protein 0.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.43 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 177 (ECOG 1): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.05 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.35 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.05 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 213: M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.35 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.41 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 9.24 mmol/L.
- Day 345 (ECOG 1): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.96 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 1.14 g/L; Beta 2 Microglobulin 1.98 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 429 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 8.98 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.49 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 492 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.12 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.92 g/L; Immunoglobulin M 5.07 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 604 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.27 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 1.36 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 5.78 mmol/L.
- Day 674 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.17 mg/dL; Immunoglobulin G 9.62 g/L; Immunoglobulin A 2.39 g/L; Immunoglobulin M 1.07 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.68 mmol/L.
- Day 757 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.4 mg/dL; Beta 2 Microglobulin 1.93 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 3.9 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.56 mmol/L.
- Day 898: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 1.22 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -19: Weight: 76 kg; Height: 169 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2128_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2128_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
